Gene-level copy-number profile of tumor specimen TCGA-61-2003-01A from TCGA case TCGA-61-2003, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.7 years (19,605 days).
Specimen TCGA-61-2003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f7c3b854-9d24-4afd-9bae-a24d86227610.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2003-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1cfef264-48cd-4853-80a5-abed3e463b13

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 537; copy number 2: 15,574; copy number 3: 19,280; copy number 4: 11,626; copy number 5: 4,136; copy number 6: 7,081; copy number 7: 362; copy number 8: 1,074; copy number 9: 2; copy number 12: 40; copy number 13: 80; copy number 14: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2003-01A-01D-0663-01): tumor purity 0.47, ploidy 3.66, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,579 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:105,433,994–105,434,821, 1 gene, copy number 7: CDK4P1.
- chr1:223,220,819–248,919,946, 636 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:102,453,367–103,003,897, 2 genes, copy number 9: AL357139.1, Z98755.1.
- chr7:38,256,337–38,378,804, 21 genes, copy number 14 (within-gene range 6–14): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2.
- chr7:142,636,924–142,779,537, 18 genes, copy number 8: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1.
- chr10:44,712–18,543,557, 316 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).
- chr10:20,547,171–25,161,236, 80 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr10:28,050,993–28,682,932, 15 genes, copy number 8: MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI.
- chr10:36,089,086–38,150,293, 38 genes, copy number 8 (within-gene range 5–8): AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A.
- chr19:27,638,483–39,642,401, 441 genes, copy number 7–13 (broad region; genes not listed).
- chr20:32,561,093–32,858,751, 11 genes, copy number 8: AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
